Somatic mutation profile of tumor specimen MMRF_1364_1_BM_CD138pos (aliquot MMRF_1364_1_BM_CD138pos_T1_KAS5U_L00684) from MMRF case MMRF_1364, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,619 days).
Specimen MMRF_1364_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2df96899-117d-41fa-876f-cdcfe1e0a3d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1364_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1364_1_PB_Whole_C2_KAS5U_L00692; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e7ef0cc-0083-4836-8ae5-7ae9817bda83

The open-access MAF lists 90 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 18, Silent 11, Intron 10, 5'UTR 5, 5'Flank 5, 3'Flank 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 171/181 reads (94%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as rs1417904174, COSV58323599; called by muse, mutect2, varscan2
- ANKS6 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs780586485, COSV62048625; called by muse, mutect2, varscan2
- APLP1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1185260129; called by muse, mutect2, varscan2
- BRWD3 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100956043; called by muse, mutect2
- CARNMT1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs752735235; called by muse, mutect2, varscan2
- FBN2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV52534602; called by muse, mutect2, varscan2
- HACL1 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 147/290 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1408794033; called by muse, mutect2, varscan2
- IGHV2-70 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 81/88 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs568002484; called by muse, varscan2
- IGKV1-5 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs762420806; called by muse, varscan2
- IGSF6 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs1291319660; called by muse, mutect2, varscan2
- KDM3B | c.4216C>T p.R1406W | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770809169, CM1412551, COSV100070318; called by muse, mutect2, varscan2
- LHX6 | c.70-4G>A | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100493613; called by muse, mutect2, varscan2
- LRP3 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs746948080, COSV99471905; called by muse, mutect2, varscan2
- MALRD1 | c.3079G>A p.G1027S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs951215089; called by muse, mutect2
- RBAK | c.1577T>C p.F526S | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs773458820; called by muse, mutect2, varscan2
- RFT1 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 159/302 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs751980698, COSV56250013; called by muse, mutect2, varscan2
- SYTL5 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 89/92 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs371238169, COSV52902901; called by muse, mutect2, varscan2
- TP53 | c.873del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 125/167 reads (75%) | catalogued as COSV52664629, COSV52760527, COSV52774013; called by mutect2, pindel, varscan2
- ARHGAP28 | c.1255A>T p.I419F (on ENST00000383472 / NM_001366230.1; = p.I260F on NM_001010000.3) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARPP21 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CDC20 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CDHR2 | c.2680G>C p.V894L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CEP89 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2
- CFAP70 | c.2563C>A p.Q855K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CMYA5 | c.10730T>C p.I3577T | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CREBBP | c.1233_1234del p.S412Tfs*14 | Frame Shift Del (DEL) | VAF 102/138 reads (74%) | called by mutect2, pindel, varscan2
- DOP1A | c.6542T>G p.L2181* | Nonsense Mutation (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- EDEM1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LYPD4 | c.611A>G p.H204R | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MLLT3 | c.162C>G p.H54Q | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC16 | c.34694G>A p.S11565N | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PIK3C3 | c.1995G>T p.L665F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PLAA | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 122/201 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLQ | c.6527A>T p.Q2176L | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- RASEF | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SHOX2 | c.859G>A p.A287T (on ENST00000441443 / NM_006884.3; = p.A311T on NM_003030.4) | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- TIGD3 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- USP14 | c.155C>A p.T52K | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- AEBP1 | c.1458G>T p.V486= | Silent (SNP) | VAF 150/328 reads (46%) | called by muse, mutect2, varscan2
- APOL6 | c.642C>T p.S214= | Silent (SNP) | VAF 49/53 reads (92%) | catalogued as rs575853273; called by muse, mutect2, varscan2
- COL15A1 | c.963G>A p.E321= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as COSV66644954; called by muse, mutect2, varscan2
- CT83 | c.213A>C p.P71= | Silent (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- EPB41L3 | c.2130G>A p.Q710= | Silent (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- GTF2E1 | c.1116G>A p.V372= | Silent (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- H4C2 | c.213G>T p.V71= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs764139318, COSV55140179; called by mutect2, varscan2
- LRRC47 | c.399C>T p.S133= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- PRRG3 | c.78G>A p.E26= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- PTCD1 | c.498G>A p.E166= | Silent (SNP) | VAF 56/126 reads (44%) | called by muse, mutect2, varscan2
- SPTB | c.5676T>C p.C1892= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- ADGRV1 | c.4378+1178T>C | Intron (SNP) | VAF 85/175 reads (49%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.2248-141T>C | Intron (SNP) | VAF 22/51 reads (43%) | catalogued as rs983830577; called by muse, mutect2, varscan2
- ANKRD30B | c.2491-20C>T | Intron (SNP) | VAF 4/56 reads (7%) | catalogued as rs1478776946; called by muse, mutect2
- ARHGDIB | c.*184G>T | 3'UTR (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- AUTS2 | c.-454G>A | 5'UTR (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- BBS5 | c.*1993C>G | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- CACNA1C | chr12:2692178 A>C | 3'Flank (SNP) | VAF 30/37 reads (81%) | called by muse, mutect2, varscan2
- CASKIN1 | c.*1242G>A | 3'UTR (SNP) | VAF 23/26 reads (88%) | catalogued as rs1025164485; called by muse, mutect2, varscan2
- CCDC112 | chr5:115267198 A>T | 3'Flank (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- CEP89 | c.-5C>T | 5'UTR (SNP) | VAF 68/130 reads (52%) | called by muse, mutect2, varscan2
- DUOX2 | c.1398+12T>A | Intron (SNP) | VAF 98/227 reads (43%) | called by muse, mutect2, varscan2
- FOXP2 | c.1094+322T>C | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- HECTD4 | c.*404G>A | 3'UTR (SNP) | VAF 20/20 reads (100%) | catalogued as rs1192655297; called by muse, mutect2, varscan2
- HSPA2 | chr14:64531987 G>T | 5'Flank (SNP) | VAF 75/161 reads (47%) | called by muse, mutect2, varscan2
- HSPA2 | chr14:64533090 G>A | 5'Flank (SNP) | VAF 12/34 reads (35%) | catalogued as rs1415945204; called by muse, mutect2, varscan2
- IFITM10 | c.*1475G>A | 3'UTR (SNP) | VAF 225/441 reads (51%) | catalogued as rs1016679960; called by muse, mutect2, varscan2
- IL27 | c.*48C>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- INTS14 | chr15:65611281 del TCCCGGAGGGACGCTAGGGGGCGCGGCC | 5'Flank (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- LIAS | c.299+1490C>T | Intron (SNP) | VAF 25/26 reads (96%) | catalogued as rs752422803; called by muse, mutect2, varscan2
- LINC02203 | c.-788+537C>G | Intron (SNP) | VAF 148/154 reads (96%) | called by muse, mutect2, varscan2
- LSMEM1 | c.-332C>T | 5'UTR (SNP) | VAF 80/154 reads (52%) | called by muse, mutect2, varscan2
- PARP12 | c.*8G>T | 3'UTR (SNP) | VAF 164/330 reads (50%) | called by muse, mutect2
- PCLAF | chr15:64382601 T>A | 5'Flank (SNP) | VAF 20/43 reads (47%) | catalogued as rs1013084834; called by muse, mutect2, varscan2
- PDE8A | c.*154G>A | 3'UTR (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- QTRT1 | c.786-78G>A | Intron (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- RAB11FIP1 | c.*1904G>T | 3'UTR (SNP) | VAF 77/83 reads (93%) | called by muse, mutect2, varscan2
- RASEF | c.*1908G>T | 3'UTR (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- RBBP8 | c.-320G>A | 5'UTR (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- RSRC1 | c.320+8228C>A | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, varscan2
- SCYL2 | c.*2187C>A | 3'UTR (SNP) | VAF 32/32 reads (100%) | called by muse, mutect2, varscan2
- SGK1 | c.550-29C>T | Intron (SNP) | VAF 36/37 reads (97%) | catalogued as rs754481279; called by muse, mutect2, varscan2
- SLC22A17 | n.403del | RNA (DEL) | VAF 36/50 reads (72%) | catalogued as rs1347491320; called by mutect2, pindel, varscan2
- SLC25A36 | c.*1896_*1900del | 3'UTR (DEL) | VAF 29/67 reads (43%) | called by mutect2, pindel, varscan2
- SPRYD7 | c.*1220A>T | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- TENM1 | c.*3791dup | 3'UTR (INS) | VAF 12/14 reads (86%) | catalogued as rs937364441; called by mutect2, varscan2
- TMSB4X | chrX:12975590 C>T | 5'Flank (SNP) | VAF 130/135 reads (96%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TRIM59 | c.*1514A>C | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- TTYH3 | c.*2205T>C | 3'UTR (SNP) | VAF 125/236 reads (53%) | called by muse, mutect2, varscan2
- TWIST1 | c.-222G>T | 5'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- UBLCP1 | c.*340A>G | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs1025154943; called by muse, mutect2, varscan2
- UGCG | c.*1539A>G | 3'UTR (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
